Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A879, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A879-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-0-3

Adenocarcinoma, acinar
814013
Site Prostate NOS
261.9
JW 11/21/13

SURGICAL PATHOLOGY REPORT
FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service: Urology

Accession #: [REDACTED]

Location

Gender: M

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

PROSTATE, LAPAROSCOPIC RADICAL PROSTATECTOMY

- ADENOCARCINOMA, GLEASON'S GRADE 4 + 5 = SCORE OF 9
- TUMOR PRESENT WITHIN THE RIGHT APEX AND RIGHT BASE
- MARGINS FREE OF TUMOR
- SEE SYNOPSIS

SEMINAL VESICLES, BILATERAL, EXCISION

- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, PELVIC, BILATERAL, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'prostate,' consisting of a 52-gram, 4.5 x 4 x 3 cm prostate with attached seminal vesicles. The right seminal vesicle measures 2.5 x 1 x 1 cm and the left seminal vesicle measures 2 x 1 x 1 cm. Inked. Tissue sampled for tumor bank. Rest for permanents," by Microscopic Description and Comment: Substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old man with prostate cancer. Operative procedure:

Laparoscopic radical prostatectomy.

Specimen(s) Received:

A: PROSTATE

[page 2 of 4]
Patient Name: [REDACTED]

B: LYMPH NODE, BILATERAL PELVIC

Gross Description

The specimens are received in two formalin-filled containers, each labeled [REDACTED]. The first container is labeled "prostate." It contains a prostate as described in the intraoperative consultation, measuring 4.5 cm from base to apex, 4 cm bilaterally and 3 cm from anterior to posterior. The right seminal vesicle measures 2.5 x 1 x 1 cm and the left seminal vesicle measures 2 x 1 x 1 cm. The urethra is probed patent. There are bilateral defects where tissue is taken for research purposes. The specimen is serially sectioned to show yellow-tan spongy parenchyma without grossly identifiable nodule. The seminal vesicle is sectioned to show unremarkable parenchyma. Labeled A1 - right apical margin shave; A2 - left apical margin shave; A3 - right bladder neck shave; A4 - left bladder neck shave; A5 and A6 - right apex; A7 and A8 - left apex; A9 - right base; A10 - right base with right seminal vesicle; A11 - left base; A12 - left base with left seminal vesicle. Jar 2. The second container is labeled "bilateral pelvic lymph nodes." It contains multiple pieces of yellow-tan fibrofatty tissue measuring in aggregate 2.5 x 2.5 x 1.0 cm. Serially sectioned to show two grossly identifiable lymph nodes measuring 0.7 x 0.7 x 0.5 cm and 0.5 x 0.5 x 0.5 cm. Labeled B1 - grossly identifiable lymph node; B2 and B3 - remainder of the fibrofatty tissue. Jar 0.

A. PROSTATE:

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 10

GLEASON'S GRADE

The Gleason's Grade is 4+5

TUMOR LOCATION

The location of the tumor involves the
right base
right apex

PERINEURAL INVASION

Perineural Invasion is identified

VASCULAR INVASION

Vascular Invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is absent

SEMINAL VESICLES

Seminal vesicles are free of tumor

[page 3 of 4]
Patient Name: [REDACTED]

SAMPLED SPECIMEN MARGINS

All sampled surgical margins are free of tumor

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows nodular hyperplasia

The non-neoplastic prostate shows PIN, high grade, focal

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Bilateral pelvic: 0/2

PRIMARY TUMOR (T)

Tumor involves more than one-half of one lobe but not both lobes (T2b)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

No distant metastasis (M0)

STAGE GROUPING

Based on this information, the overall AJCC/UICC stage of the tumor is T2/N0/M0/Gleason score 4+5 (Stage II)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

The performance characteristics of some immunohistochemical stains, fluorescence in-situ hybridization tests and immunophenotyping by flow cytometry cited in this report (if any) were determined by the

as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Act of 1988 (CLIA '88). Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Department of Health and Human Services as a high complexity laboratory under CLIA '88. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report:

This test was developed and its performance characteristics determined by the Surgical Pathology Department of [REDACTED] It has not been cleared or approved by the U. S. Food and Drug Administration.

	Yes	No

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason score on the initial pathology report is $4+5=9$	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Top slide review Gleason score is $3+4=7$	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The top slide review showed a different Gleason score from the Gleason score on the initial Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 4dc03b77-854c-4fc2-ba0f-66f5b02427f1 (TCGA-VP-A879.526F7E5C-B681-46B7-B118-10AB3F2DD30E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).